MMRF case MMRF_2251 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b086e8b6-0a9c-47c7-8783-323650c7def6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Dead; Days to death: 104 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 47.1 years (17,192 days); ISS stage: III; Days to last known disease status: 104 days; Days to last follow up: 104 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 21 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 99 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 104.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 83.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 2.1 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 9 µg/mL; Lactate Dehydrogenase 5.28 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 126 µmol/L; Calcium 2.41 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 4.3 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 50 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 20.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 79 µmol/L; Calcium 2.1 mmol/L; Glucose 6.4 mmol/L.

Other clinical attributes
- Day -20: Weight: 58 kg; Height: 172 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2251_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_2251_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
